Somatic mutation profile of tumor specimen TCGA-MP-A4TJ-01A (aliquot TCGA-MP-A4TJ-01A-51D-A25L-08) from TCGA case TCGA-MP-A4TJ, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.6 years (22,875 days).
Specimen TCGA-MP-A4TJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cf9bf59-9c38-4e3c-b443-f742257b9a45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4TJ-10A (Blood Derived Normal), aliquot TCGA-MP-A4TJ-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12be6421-142b-47f2-889c-68f983d091ba

The open-access MAF lists 103 somatic variants for this specimen: 77 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 24, Nonsense Mutation 9, Frame Shift Del 4, 3'UTR 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- STK11 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 2/15 reads (13%) | hotspot (GDC flag); catalogued as rs1359582062, CD051785, CM044076, COSV58820485, COSV58828619, COSV58831044; called by muse, mutect2
- ABCA13 | c.14671T>C p.S4891P | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101291286; called by muse, mutect2, varscan2
- ABCB5 | c.2865C>T p.F955= (on ENST00000404938 / NM_001163941.2; = p.F510= on NM_178559.6) | Splice Region (SNP) | VAF 10/76 reads (13%) | catalogued as rs1278929079, COSV99328031; called by muse, mutect2
- ACO1 | c.266+1G>T p.X89_splice | Splice Site (SNP) | VAF 14/100 reads (14%) | catalogued as COSV59379534, COSV59381007; called by muse, mutect2, varscan2
- ADAMTS12 | c.457G>T p.G153W | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100710645; called by muse, mutect2, varscan2
- AKR1C8P | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs555305935; called by muse, mutect2
- APCDD1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs755924933, COSV100789934; called by muse, mutect2, varscan2
- ATM | c.3994-2A>T p.X1332_splice | Splice Site (SNP) | VAF 13/60 reads (22%) | catalogued as CS1411616, COSV53772840, COSV99589030; called by muse, mutect2
- BAG2 | c.371T>G p.F124C | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.67); catalogued as COSV58099664; called by muse, mutect2, varscan2
- CGN | c.2576A>G p.E859G | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1324093837, COSV99642170; called by muse, mutect2
- CHSY1 | c.2239C>T p.H747Y | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99573794; called by muse, mutect2
- CNTNAP5 | c.1394C>G p.T465S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV101443347; called by muse, mutect2, varscan2
- CRX | c.101G>T p.S34I | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV99704415; called by muse, mutect2, varscan2
- DNAJA3 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV52161305, COSV99276610; called by muse, mutect2, varscan2
- EIF4E | c.172G>C p.A58P | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV99794735; called by muse, mutect2, varscan2
- ELN | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV52711329; called by muse, mutect2, varscan2
- ENOX2 | c.486G>T p.K162N (on ENST00000338144 / NM_001382520.1; = p.K133N on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100584021; called by muse, mutect2, varscan2
- GABBR1 | c.925A>T p.I309F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as COSV100589599; called by muse, mutect2, varscan2
- GABRA3 | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100942569; called by muse, mutect2, varscan2
- HCRTR1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65484733; called by muse, mutect2, varscan2
- HIPK3 | c.125G>C p.R42P | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV100305629; called by muse, mutect2, varscan2
- HMCN1 | c.3986C>T p.T1329I | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV99627413; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.994G>T p.G332C (on ENST00000354667 / NM_031243.3; = p.G320C on NM_002137.4) | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100668232; called by muse, mutect2, varscan2
- KRT3 | c.783C>A p.Y261* | Nonsense Mutation (SNP) | VAF 28/233 reads (12%) | catalogued as rs1422175777, COSV100526999; called by muse, mutect2, varscan2
- KRT9 | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 49/291 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV99879132; called by muse, mutect2, varscan2
- LDHAL6A | c.449T>C p.L150S | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99323850; called by muse, mutect2
- LPAR1 | c.661A>T p.M221L | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100730786; called by muse, mutect2, varscan2
- MEGF10 | c.1510G>T p.G504W | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57257411, COSV99174837; called by muse, mutect2, varscan2
- MMP16 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54177800; called by muse, mutect2
- MYH4 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99700957; called by muse, mutect2
- NOS1 | c.411C>G p.H137Q | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV100500372; called by muse, mutect2
- NSUN5 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as rs376991537; called by muse, mutect2, varscan2
- OR13G1 | c.423G>T p.L141F | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV100687177; called by muse, mutect2
- OR4C46 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100060583; called by muse, mutect2, varscan2
- OR8H2 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 90/639 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV100542254; called by muse, mutect2, varscan2
- OXSR1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs777107244, COSV61260665; called by muse, mutect2, varscan2
- PCDHGA9 | c.1463T>C p.I488T | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99535403; called by muse, mutect2
- PCSK1 | c.1993del p.Q665Rfs*43 | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | catalogued as CM132638; called by mutect2, pindel, varscan2
- PMS2 | c.1826T>G p.V609G | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV99764113; called by muse, mutect2
- POSTN | c.1000G>C p.D334H | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101123302; called by muse, mutect2
- PPP1R3A | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV99492500; called by muse, mutect2
- PRKCH | c.1258T>C p.F420L | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV100273139; called by muse, mutect2
- PSG9 | c.1048C>A p.L350I | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.949); catalogued as COSV99392170; called by muse, mutect2, varscan2
- RIOK1 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.074); catalogued as COSV53572896; called by muse, mutect2
- S1PR3 | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.293); catalogued as COSV100822505; called by muse, mutect2, varscan2
- SEL1L2 | c.850A>T p.I284L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99532984; called by muse, mutect2, varscan2
- SIGLEC11 | c.1491C>G p.N497K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV101389261; called by muse, mutect2, varscan2
- SLC22A8 | c.1453G>C p.G485R | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100267779; called by muse, mutect2, varscan2
- SLC28A3 | c.453C>G p.Y151* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100883214, COSV66152894; called by muse, mutect2, varscan2
- SORCS3 | c.1180del p.L394Wfs*12 | Frame Shift Del (DEL) | VAF 15/151 reads (10%) | catalogued as COSV63803824; called by mutect2, pindel, varscan2
- SPATA19 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV100141079, COSV54484790; called by muse, mutect2, varscan2
- SPTA1 | c.5188G>T p.E1730* | Nonsense Mutation (SNP) | VAF 16/230 reads (7%) | catalogued as COSV100934701, COSV63753616; called by muse, mutect2
- SPTB | c.3367T>A p.S1123T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV101072043; called by muse, mutect2, varscan2
- STAC3 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.206); catalogued as COSV100234557; called by muse, mutect2, varscan2
- STYXL2 | c.2210A>T p.Q737L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99608982; called by muse, mutect2
- TDRD1 | c.3026G>A p.R1009H | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1288304923, COSV52590010; called by muse, mutect2
- THSD1 | c.68A>T p.E23V | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99318831; called by muse, mutect2
- TMEM145 | c.170T>A p.L57Q | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100003752; called by muse, mutect2, varscan2
- TMEM8B | c.618C>A p.Y206* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100941583, COSV65077933; called by muse, mutect2, varscan2
- TNR | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.839); catalogued as rs750335506, COSV54882695; called by muse, mutect2, varscan2
- UHRF2 | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV99436434; called by muse, mutect2
- ZFHX4 | c.10436C>A p.A3479E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99029622; called by muse, mutect2, varscan2
- ZNF131 | c.232A>T p.S78C | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100185359; called by muse, mutect2
- ZNF554 | c.731T>C p.L244S | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100421163; called by muse, mutect2, varscan2
- FCRL2 | c.1107G>T p.E369D | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.534); called by muse, mutect2
- GUCY1A2 | c.928T>C p.S310P | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); called by muse, mutect2
- IGKV1-17 | c.248G>T p.R83M | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- INTS1 | c.2836A>T p.K946* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- KRT73 | c.29del p.G10Efs*108 | Frame Shift Del (DEL) | VAF 14/101 reads (14%) | called by mutect2, pindel, varscan2
- LGR4 | c.950del p.G317Efs*8 | Frame Shift Del (DEL) | VAF 26/223 reads (12%) | called by mutect2, pindel, varscan2
- MUC2 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated, low confidence (0.59); called by muse, mutect2, varscan2
- NBAS | c.2161A>T p.R721* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- PLG | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); called by muse, mutect2
- SEMA4G | c.1829A>G p.Y610C (on ENST00000370250; = p.Y615C on NM_017893.3) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- TRGV5 | c.344C>A p.T115N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VIT | c.1975C>T p.Q659* (on ENST00000389975 / NM_001177969.1; = p.Q674* on NM_053276.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- ABCA9 | c.930T>C p.Y310= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs1345815052, COSV100382953; called by muse, mutect2, varscan2
- ADD2 | c.1137A>G p.T379= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV100035313; called by muse, mutect2
- ADGRG7 | c.171C>A p.T57= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV99840863; called by muse, mutect2
- C7orf50 | c.351G>A p.R117= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100657442; called by muse, mutect2
- CDCP2 | c.1245C>T p.L415= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100313423; called by muse, mutect2
- DLGAP1 | c.207C>G p.T69= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100229491, COSV59824609; called by muse, mutect2, varscan2
- EXOC7 | c.1890C>A p.I630= (on ENST00000335146 / NM_001145297.4; = p.I548= on NM_015219.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100135101; called by muse, mutect2, varscan2
- FREM1 | c.4650C>G p.P1550= | Silent (SNP) | VAF 30/223 reads (13%) | called by muse, mutect2, varscan2
- GRM3 | c.525C>T p.S175= | Silent (SNP) | VAF 14/216 reads (6%) | catalogued as COSV64468430, COSV64470873; called by muse, mutect2
- GXYLT1 | c.507A>G p.L169= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1288615996, COSV99788170; called by muse, mutect2, varscan2
- MAN2A1 | c.1773G>C p.S591= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV99810852; called by muse, mutect2
- MED31 | c.321C>T p.H107= | Silent (SNP) | VAF 33/182 reads (18%) | catalogued as COSV99854523; called by muse, mutect2, varscan2
- MME | c.348C>T p.V116= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs1459481415, COSV64707149; called by muse, mutect2, varscan2
- OR2T33 | c.339A>G p.L113= | Silent (SNP) | VAF 17/186 reads (9%) | catalogued as COSV100531533, COSV100531784; called by muse, mutect2, varscan2
- PACS2 | c.2577C>T p.S859= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as rs782503189; called by muse, mutect2
- PRAMEF1 | c.1017C>A p.P339= | Silent (SNP) | VAF 29/400 reads (7%) | catalogued as COSV100179623, COSV60011631; called by muse, mutect2
- PTPRD | c.2148C>A p.R716= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as COSV100644192; called by muse, mutect2, varscan2
- SLITRK1 | c.1080C>T p.N360= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as COSV100999897; called by muse, mutect2, varscan2
- SP140 | c.1788G>T p.G596= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as COSV100613631; called by muse, mutect2
- STK11 | c.492G>T p.L164= | Silent (SNP) | VAF 2/16 reads (13%) | called by muse, mutect2
- UPK1A | c.711G>T p.G237= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1401978868; called by muse, mutect2
- VN1R4 | c.498C>T p.Y166= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV100237395; called by muse, mutect2, varscan2
- ZBED9 | c.3411A>G p.K1137= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV101509203; called by muse, mutect2, varscan2
- ZNF804A | c.3057A>G p.T1019= | Silent (SNP) | VAF 13/201 reads (6%) | catalogued as COSV100167319; called by muse, mutect2
- ANKRD13D | c.*1468G>A | 3'UTR (SNP) | VAF 10/93 reads (11%) | catalogued as rs749097377, COSV100354761, COSV57385848; called by muse, mutect2, varscan2
- FNDC7 | c.*1C>G | 3'UTR (SNP) | VAF 4/64 reads (6%) | catalogued as COSV99601115; called by muse, mutect2
